Surgical pathology report (de-identified scan), TCGA case TCGA-KB-A93J, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University Health Network, Toronto, specimen TCGA-KB-A93J-01A (Primary Tumor).

[page 1 of 4]
DEPARTMENT OF PATHOLOGY

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

M

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering MD:

Copy To:

Specimen(s) Received

1. Stom-Resection: TOTAL STOMACH & DISTAL ESOPHAGUS QS ON ESOPHAGEAL MARGIN (QS)
2. Soft Tissue: Para-esophageal tissue
3. Soft Tissue: Final esophageal margin
4. Surgical Waste

Diagnosis

1. Total gastrectomy and distal esophagectomy: Poorly differentiated adenocarcinoma, stomach body, anterior wall. The tumor invades through the muscularis propria and extends superficially into the serosa. Lymphovascular and perineural invasion is present. The resection margins appear clear of invasive carcinoma. One of thirty-five lymph nodes positive for metastatic adenocarcinoma (1/35). See synoptic data.
2. Para-esophageal tissue: Negative for malignancy.
3. Final esophageal margin: Negative for malignancy.
4. Surgical Waste: No section submitted. See gross.

CHF IAD-0-3
Adenocarcinoma, diffuse 8/45/13
with
Adenocarcinoma, intestinal type 8/44/13
CHF Site Gastroesophageal junction C16.0
with Body of stomach C16.2

Synoptic Data

----- MACROSCOPIC -----
Specimen Type: Other: Total gastrectomy & distal esophagectomy
Tumor Site: Body - Anterior wall
Body - Greater curvature

Tumor Configuration: Exophytic (polypoid)
Tumor Size: Greatest dimension: 8.0 cm
Additional dimensions: 7.0 x 1.2 in thickness cm

----- MICROSCOPIC -----
Histologic Type: Adenocarcinoma, intestinal type
Histologic Grade: G3: Poorly differentiated
Pathologic Staging (pTNM): pT2b: Tumor invades subserosa
pN1: Metastasis in 1 to 6 perigastric lymph nodes
Number of lymph nodes examined: 35
Number of lymph nodes involved: 1
pMX: Distant metastasis cannot be assessed

W 4/30/14

[page 2 of 4]
Surgical Pathology Consultation Report

Margins:	Proximal Margin uninvolved by invasive carcinoma Distal Margin uninvolved by invasive carcinoma Omental (Radial) Margins uninvolved by invasive carcinoma
Lymphatic (Small Vessel) Invasion (L):	Present
Venous (Large Vessel) Invasion (V):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	Intestinal metaplasia Gastritis (type): chronic gastritis

Electronically verified by:

Clinical History

STOMACH CANCER

Gross Description

1. The specimen is labeled with the patient's name and as "stom-resection: Total stomach & distal esophagus QS on esophageal margin (QS)"

Resection Specimen: Total gastrectomy

How received: Fresh

DIMENSIONS OF ESOPHAGUS:

The esophagus is submitted in toto for intraoperative consultation by frozen section (measurements not provided), with esophageal margin in toto en face.

DIMENSIONS OF STOMACH:

Length long greater curvature 31.0 cm
Length along lesser curvature 15.0 cm
Length of distal duodenum 0.6 cm
Circumference of distal duodenal margin 5.5 cm

TUMOR:

Location in relationship to gastroesophageal junction: The tumor is located on the anterior body wall of the stomach, extending to the greater curvature

Configuration: The tumor has raised borders, with a crater-like central appearance

Dimensions:

Diameters 8.0 cm in length x 7.0 cm
Thickness: 1.2 cm

Descriptive characteristics: Tan, friable

Ulceration/perforation: Not grossly identified

Distance from margins:

Proximal 2.0 cm (at time of gross dissection following previous submission of distal esophageal segment for frozen section)
Distal 5.7 cm

Estimated depth of invasion: Through muscle wall, extending into gastric serosa

[page 3 of 4]
Surgical Pathology Consultation Report

LESIONS IN NONCANCEROUS STOMACH:

None grossly identified. The gastric rugae are flattened.

LYMPH NODES:

Multiple lymph nodes ranging from 0.1 - 1.8 cm are identified within perigastric tissue.

TISSUE BANKING:

The tumor (four pieces) and normal tissue (three pieces) are sampled for tissue banking.

Representative sections are submitted as follows:

- 1A frozen section block resubmitted, proximal esophageal margin in toto en face, with distal esophageal segment in toto
- 1B perpendicular section from proximal margin/gastroesophageal junction at time of gross dissection
- 1C grossly unremarkable stomach proximal to tumor
- 1D-1K gastric tumor sampled from proximal to distal (serosa painted with silver nitrate)
- 1L grossly unremarkable stomach distal to tumor
- 1M pylorus
- 1N distal duodenal margin in toto en face
- 1O-1P lesser curvature perigastric tissue, one lymph node serially sectioned
- 1Q lesser curvature perigastric tissue, one bisected lymph node
- 1R-1T lesser curvature perigastric tissue, three lymph nodes per block
- 1U-1X lesser curvature perigastric tissue, four lymph nodes per block
- 1Y greater curvature perigastric tissue, one bisected lymph node
- 1Z greater curvature perigastric tissue, three lymph nodes

2. The specimen is labeled with the patient's name and as "soft tissue: Para-esophageal margin".

One piece of congested soft tissue measuring 1.7 x 1.0 x 0.4 cm.

2A bisected and submitted in toto

3. The specimen is labeled with the patient's name and as "soft tissue: Final esophageal margin".

Number of gray-tan soft tissue pieces: 2

Measurements: 0.7 x 0.4 x 0.3 cm to 3.0 x 1.0 x 0.4 cm.

The larger tissue piece is ragged and irregular, and infiltrated by blue suture material

The specimen is submitted in toto as follows:

3A smaller tissue piece

3B larger tissue piece (sutures removed)

4. The specimen is labeled with the patient's name and as "surgical waste".

One tubular piece of bowel tissue measuring 1.1 cm in length x 5.5 cm in circumference, stapled at one end and otherwise infiltrated by blue suture material. No sections are submitted.

Quick Section Diagnosis

1A. Esophageal margin QS:

- Negative for malignancy

*Per TSS dx discrepancy form,
TCGA Tumor is Stomach adenocarcinoma,
diffuse type.*

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Adenocarcinoma NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Adenocarcinoma: Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Initial pathology report focused on all of the tissue. The CQCF refers to assessment of the specific block/ tissue sent to TCGA.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has reviewed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file d7448721-da61-41a3-86c3-0f609648d478 (TCGA-KB-A93J.9747C9BD-3F58-48B6-9068-E5E04070B15A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).